Somatic mutation profile of tumor specimen TARGET-10-PANWDL-09A (aliquot TARGET-10-PANWDL-09A-01D) from TARGET case TARGET-10-PANWDL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,414 days).
Specimen TARGET-10-PANWDL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae497568-eccf-4af1-8fb2-b883645b95fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWDL-10A (Blood Derived Normal), aliquot TARGET-10-PANWDL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b379721-bd21-4f44-a8c5-2281153cfe10

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 3, Missense Mutation 2, Silent 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.13666G>A p.A4556T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs189345192, CM056385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPAT | c.1681_1682insGG p.K561Rfs*21 | Frame Shift Ins (INS) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.260_261insTT p.M88* | Frame Shift Ins (INS) | VAF 48/120 reads (40%) | called by mutect2, varscan2
- TBL1XR1 | c.259delinsCTT p.V87Lfs*2 | Frame Shift Ins (INS) | VAF 50/133 reads (38%) | called by mutect2*, pindel, varscan2*
- TSPAN31 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- KCNB2 | c.1425C>T p.S475= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV73049433; called by muse, mutect2, varscan2
- NOTUM | c.1482C>T p.N494= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs777868773, COSV104433690; called by muse, mutect2, varscan2
- TMPRSS4 | c.-60C>T | 5'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
